Somatic mutation profile of tumor specimen TARGET-10-PAREJA-09A (aliquot TARGET-10-PAREJA-09A-01D) from TARGET case TARGET-10-PAREJA, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 7.1 years (2,593 days).
Specimen TARGET-10-PAREJA-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 57e882de-1eb8-459e-a8f6-0a08ad3c5d2f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PAREJA-10A (Blood Derived Normal), aliquot TARGET-10-PAREJA-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/91a72d37-a3ac-4541-b684-43f5cd8f446d

The open-access MAF lists 26 somatic variants for this specimen: 18 protein-altering or splice-affecting, 5 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 16, Silent 5, Splice Region 1, Nonsense Mutation 1, RNA 1, Intron 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FLT3 | c.2516A>G p.D839G | Missense Mutation (SNP) | VAF 21/45 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.89); catalogued as rs991132188, COSV54045448; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ACTRT1 | c.112G>A p.V38I | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.031); catalogued as rs138725538, COSV64418994; called by muse, mutect2, varscan2
- CEP250 | c.2455C>T p.R819W | Missense Mutation (SNP) | VAF 13/23 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1256686850, COSV61171399; called by muse, mutect2, varscan2
- CHRNA1 | c.1073G>A p.R358Q (on ENST00000261007 / NM_001039523.3; = p.R333Q on NM_000079.4) | Missense Mutation (SNP) | VAF 18/32 reads (56%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs960551244; called by muse, mutect2
- DPYD | c.762+7G>A | Splice Region (SNP) | VAF 19/46 reads (41%) | catalogued as rs1247255465; called by muse, mutect2, varscan2
- GCGR | c.217G>A p.A73T | Missense Mutation (SNP) | VAF 13/26 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.217); catalogued as rs868431560, COSV68779907; called by muse, mutect2, varscan2
- PCDH10 | c.2939C>T p.S980F | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.459); catalogued as COSV104386940; called by muse, mutect2, varscan2
- PCDHA4 | c.1684G>A p.A562T | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.12); catalogued as COSV63543187; called by muse, mutect2
- PKHD1L1 | c.8537G>A p.R2846H | Missense Mutation (SNP) | VAF 44/135 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs375835470; called by muse, mutect2, varscan2
- REG1B | c.201G>A p.M67I | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as COSV59305802, COSV59307627; called by muse, mutect2, varscan2
- TXNDC11 | c.2150C>T p.P717L (on ENST00000356957 / NM_001303447.2; = p.P690L on NM_015914.7 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 21/71 reads (30%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.631); catalogued as rs751752980; called by muse, mutect2, varscan2
- URGCP | c.763G>A p.V255M (on ENST00000453200 / NM_001077663.3; = p.V246M on NM_017920.4) | Missense Mutation (SNP) | VAF 28/45 reads (62%) | SIFT tolerated (0.07); PolyPhen benign (0.014); catalogued as rs187984430; called by muse, mutect2, varscan2
- ZFHX4 | c.6394C>A p.P2132T | Missense Mutation (SNP) | VAF 38/115 reads (33%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as COSV50663862; called by muse, mutect2, varscan2
- ZNF516 | c.530C>T p.S177F | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.452); catalogued as rs774299625, COSV101487179; called by muse, varscan2
- CHIA | c.687C>A p.Y229* (on ENST00000343320; = p.Y121* on NM_021797.4 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 33/78 reads (42%) | called by muse, mutect2, varscan2
- PCSK5 | c.4390G>A p.D1464N | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT tolerated (0.25); PolyPhen benign (0); called by muse, mutect2, varscan2
- PRDM5 | c.110C>T p.P37L | Missense Mutation (SNP) | VAF 50/156 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PRDM5 | c.109C>T p.P37S | Missense Mutation (SNP) | VAF 51/154 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ANKRD30A | c.1119G>A p.T373= (on ENST00000611781; = p.T317= on NM_052997.2) | Silent (SNP) | VAF 102/302 reads (34%) | catalogued as rs768361506, COSV64614767, COSV64615588; called by muse, mutect2, varscan2
- DDC | c.492C>T p.I164= | Silent (SNP) | VAF 8/18 reads (44%) | called by muse, mutect2
- FLNA | c.2631C>T p.A877= | Silent (SNP) | VAF 25/81 reads (31%) | catalogued as rs373378793; called by muse, mutect2, varscan2
- SLC9A3R1 | c.948C>T p.S316= | Silent (SNP) | VAF 10/38 reads (26%) | called by muse, mutect2
- TET3 | c.1455T>A p.P485= | Silent (SNP) | VAF 21/45 reads (47%) | called by muse, mutect2, varscan2
- CHMP1A | c.381+63C>T | Intron (SNP) | VAF 9/26 reads (35%) | catalogued as rs762454531; called by muse, mutect2, varscan2
- GLRXP3 | n.227G>A | RNA (SNP) | VAF 35/99 reads (35%) | called by muse, mutect2, varscan2
- SPACA4 | c.-63G>A | 5'UTR (SNP) | VAF 7/22 reads (32%) | catalogued as rs1035544002; called by muse, mutect2
